Somatic mutation profile of tumor specimen TCGA-CW-5590-01A (aliquot TCGA-CW-5590-01A-01D-1534-10) from TCGA case TCGA-CW-5590, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 51.8 years (18,905 days).
Specimen TCGA-CW-5590-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2c02c5d-eb61-4f3b-aa9a-6800d8739ade.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CW-5590-11A (Solid Tissue Normal), aliquot TCGA-CW-5590-11A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2aafd74-de55-4762-abdc-0c1119cebdca

The open-access MAF lists 79 somatic variants for this specimen: 59 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 17, Nonsense Mutation 8, Frame Shift Del 7, Intron 2, In Frame Del 2, 3'Flank 1, In Frame Ins 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SETD2 | c.4874G>A p.R1625H | Missense Mutation (SNP) | VAF 250/620 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57431794, COSV57438402; called by muse, mutect2, varscan2
- ATP8A1 | c.2797G>T p.A933S | Missense Mutation (SNP) | VAF 158/642 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs950046694; called by muse, mutect2, varscan2
- CHGB | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV66761730; called by muse, mutect2, varscan2
- DDX58 | c.1276T>C p.Y426H | Missense Mutation (SNP) | VAF 59/261 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1002390870; called by muse, mutect2, varscan2
- GPATCH8 | c.1289A>G p.N430S | Missense Mutation (SNP) | VAF 55/623 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1172134801; called by muse, mutect2
- KCNN4 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.438); catalogued as rs1221003015; called by muse, mutect2, varscan2
- KIF13A | c.1277G>T p.R426L | Missense Mutation (SNP) | VAF 96/267 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV52444498; called by muse, mutect2, varscan2
- MUC16 | c.24287C>G p.T8096R | Missense Mutation (SNP) | VAF 101/373 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.175); catalogued as rs753425142; called by muse, mutect2, varscan2
- NOC2L | c.50A>G p.D17G | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1365774663; called by muse, varscan2
- OR5P3 | c.419T>C p.V140A | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.367); catalogued as rs1169940551; called by muse, varscan2
- PPIG | c.1261G>T p.E421* | Nonsense Mutation (SNP) | VAF 148/513 reads (29%) | catalogued as COSV53644731; called by muse, mutect2, varscan2
- SFXN2 | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1044754107; called by muse, mutect2, varscan2
- SLC41A3 | c.1468G>A p.V490M | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as rs374841928; called by muse, mutect2, varscan2
- SRRM2 | c.3206C>G p.S1069C | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); catalogued as rs1199295504; called by muse, mutect2, varscan2
- VANGL1 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777148076, COSV59620683; called by muse, mutect2, varscan2
- AAGAB | c.183T>A p.C61* | Nonsense Mutation (SNP) | VAF 137/494 reads (28%) | called by muse, mutect2, varscan2
- ANKRD12 | c.3337C>T p.R1113* | Nonsense Mutation (SNP) | VAF 15/431 reads (3%) | called by muse, mutect2
- ARHGEF26 | c.795C>A p.N265K | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- BUB1B | c.2548C>T p.H850Y | Missense Mutation (SNP) | VAF 18/439 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.134); called by muse, mutect2
- CPVL | c.1226del p.Q409Rfs*33 | Frame Shift Del (DEL) | VAF 65/250 reads (26%) | called by mutect2, pindel, varscan2
- DNAH3 | c.7346T>C p.F2449S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.242); called by muse, mutect2
- ELMOD2 | c.599T>A p.L200* | Nonsense Mutation (SNP) | VAF 152/544 reads (28%) | called by muse, mutect2, varscan2
- EPB41L3 | c.1345_1351delinsA p.G449_G451delinsS | In Frame Del (DEL) | VAF 33/92 reads (36%) | called by pindel, varscan2*
- FCGBP | c.4595G>T p.C1532F | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FN1 | c.5914del p.Y1972Mfs*5 | Frame Shift Del (DEL) | VAF 219/847 reads (26%) | called by mutect2, pindel, varscan2
- GIMAP4 | c.573C>A p.N191K | Missense Mutation (SNP) | VAF 7/173 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- GSDME | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 54/173 reads (31%) | called by muse, mutect2, varscan2
- HIVEP1 | c.1723del p.T575Lfs*24 | Frame Shift Del (DEL) | VAF 23/112 reads (21%) | called by mutect2, pindel, varscan2
- HSH2D | c.910C>G p.P304A | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.054); called by muse, mutect2
- LRRC8A | c.1121del p.F374Sfs*24 | Frame Shift Del (DEL) | VAF 14/71 reads (20%) | called by mutect2, pindel, varscan2
- MAP4K4 | c.2597A>C p.Q866P (on ENST00000347699 / NM_001242559.2; = p.Q784P on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 204/696 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MVB12B | c.478_479del p.I160Lfs*2 | Frame Shift Del (DEL) | VAF 29/206 reads (14%) | called by mutect2, pindel
- MYO18B | c.2840dup p.G948Rfs*17 | Frame Shift Ins (INS) | VAF 77/302 reads (25%) | called by mutect2, pindel, varscan2
- NOL10 | c.288A>T p.E96D | Missense Mutation (SNP) | VAF 60/393 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR1I1 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4S1 | c.617T>C p.L206S | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR51I1 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- OSR1 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- PBRM1 | c.112del p.L38Ffs*7 | Frame Shift Del (DEL) | VAF 79/224 reads (35%) | called by mutect2, pindel, varscan2
- PLEKHG1 | c.2134T>A p.S712T | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RBM47 | c.1123+2T>C p.X375_splice | Splice Site (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2
- RBPJ | c.570del p.F190Lfs*16 | Frame Shift Del (DEL) | VAF 139/564 reads (25%) | called by mutect2, pindel, varscan2
- RCAN1 | c.692T>A p.M231K | Missense Mutation (SNP) | VAF 75/209 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RNF17 | c.4152A>G p.I1384M | Missense Mutation (SNP) | VAF 69/667 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); called by muse, mutect2
- RUBCNL | c.130A>T p.I44F | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- RUBCNL | c.129C>A p.D43E | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- SCN8A | c.2451G>A p.W817* | Nonsense Mutation (SNP) | VAF 191/660 reads (29%) | called by muse, mutect2, varscan2
- SLC11A1 | c.1420_1422dup p.V474dup | In Frame Ins (INS) | VAF 31/130 reads (24%) | called by mutect2, pindel, varscan2
- SMC1B | c.963C>A p.D321E | Missense Mutation (SNP) | VAF 417/1570 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SMC2 | c.3534G>C p.K1178N | Missense Mutation (SNP) | VAF 88/520 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA31E1 | c.41_46del p.G14_R15del | In Frame Del (DEL) | VAF 8/49 reads (16%) | called by mutect2, pindel, varscan2
- SYT12 | c.465G>C p.Q155H | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.097); called by muse, mutect2
- TAT | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 72/280 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- TGM7 | c.1716C>G p.Y572* | Nonsense Mutation (SNP) | VAF 55/189 reads (29%) | called by muse, mutect2, varscan2
- TTN | c.37514C>A p.S12505* (on ENST00000591111; = p.S5081* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 77/296 reads (26%) | called by muse, mutect2, varscan2
- UGT2B10 | c.262A>G p.I88V | Missense Mutation (SNP) | VAF 67/362 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF180 | c.1036A>G p.N346D | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.615); called by muse, varscan2
- ZNF224 | c.1719T>G p.C573W | Missense Mutation (SNP) | VAF 79/250 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF93 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 48/392 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ARGFX | c.618A>G p.Q206= | Silent (SNP) | VAF 44/305 reads (14%) | called by muse, varscan2
- CYTH4 | c.402G>A p.E134= | Silent (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- DTL | c.2004C>T p.A668= | Silent (SNP) | VAF 25/91 reads (27%) | called by muse, mutect2, varscan2
- KLK15 | c.120C>T p.Y40= | Silent (SNP) | VAF 21/84 reads (25%) | called by muse, mutect2, varscan2
- KRT14 | c.1266G>A p.E422= | Silent (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- LRRC15 | c.1146G>A p.G382= | Silent (SNP) | VAF 31/129 reads (24%) | called by muse, mutect2, varscan2
- LRRK2 | c.6678C>T p.V2226= | Silent (SNP) | VAF 103/416 reads (25%) | called by muse, mutect2, varscan2
- PLEKHG1 | c.2133C>T p.G711= | Silent (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- PLSCR4 | c.660C>A p.G220= | Silent (SNP) | VAF 49/220 reads (22%) | called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.576G>A p.L192= | Silent (SNP) | VAF 32/113 reads (28%) | catalogued as rs145308601; called by muse, mutect2, varscan2
- RIMBP2 | c.234C>T p.P78= | Silent (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- SFI1 | c.1983C>T p.Y661= (on ENST00000400288 / NM_001007467.3; = p.Y630= on NM_014775.4) | Silent (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2
- SGF29 | c.747C>T p.I249= | Silent (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
- SLC12A6 | c.3373C>T p.L1125= (on ENST00000354181 / NM_001365088.1; = p.L1074= on NM_005135.2) | Silent (SNP) | VAF 60/209 reads (29%) | called by muse, mutect2, varscan2
- SRRT | c.1863C>T p.S621= | Silent (SNP) | VAF 39/130 reads (30%) | catalogued as rs929229324; called by muse, mutect2, varscan2
- TTN | c.37515A>T p.S12505= (on ENST00000591111; = p.S5081= on NM_003319.4) | Silent (SNP) | VAF 77/299 reads (26%) | called by muse, mutect2, varscan2
- ZNF800 | c.1239A>T p.A413= | Silent (SNP) | VAF 113/400 reads (28%) | called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73701074 C>T | 3'Flank (SNP) | VAF 48/186 reads (26%) | catalogued as rs1161572621; called by muse, mutect2, varscan2
- DST | c.16635+224C>T | Intron (SNP) | VAF 70/436 reads (16%) | called by muse, mutect2, varscan2
- LARP7 | c.1142+694A>T | Intron (SNP) | VAF 118/379 reads (31%) | called by muse, mutect2, varscan2
